Somatic mutation profile of tumor specimen TCGA-DJ-A1QH-01A (aliquot TCGA-DJ-A1QH-01A-21D-A14W-08) from TCGA case TCGA-DJ-A1QH, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 58.0 years (21,184 days).
Specimen TCGA-DJ-A1QH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 551e79f1-d906-45ae-8e48-9d141dc6313d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A1QH-10A (Blood Derived Normal), aliquot TCGA-DJ-A1QH-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9dbcebe-ac6d-4b4f-a43e-ba8d27c9d9b6

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 11, Silent 6, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ATN1 | c.1054del p.L352Wfs*20 | Frame Shift Del (DEL) | VAF 54/177 reads (31%) | catalogued as COSV100755823, COSV63110550; called by mutect2, pindel, varscan2
- CCDC180 | c.1209G>C p.K403N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV63834050; called by muse, mutect2, varscan2
- FLNC | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57962485; called by muse, mutect2, varscan2
- GBF1 | c.1082G>A p.C361Y (on ENST00000369983 / NM_001377137.1; = p.C360Y on NM_004193.3) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.404); catalogued as COSV64148172; called by muse, mutect2, varscan2
- LY75-CD302 | c.5134_5136del p.E1712del | In Frame Del (DEL) | VAF 24/64 reads (38%) | catalogued as rs779639279; called by pindel, varscan2
- MTHFD1 | c.1943C>T p.S648F | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53702998; called by muse, mutect2
- MYOM1 | c.3545C>T p.P1182L | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.189); catalogued as COSV55299032; called by muse, mutect2, varscan2
- OR5B3 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1364468653, COSV58678399; called by muse, mutect2
- PPEF1 | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62996459; called by muse, mutect2, varscan2
- PZP | c.740T>G p.I247R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV54368255, COSV99738250; called by muse, mutect2
- S1PR1 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 135/357 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59514267; called by muse, mutect2, varscan2
- SIM1 | c.1787A>T p.N596I | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs774106051, COSV53495512; called by muse, mutect2, varscan2
- GLRA4 | c.621T>C p.D207= | Silent (SNP) | VAF 10/254 reads (4%) | catalogued as rs1405322994, COSV65456730; called by muse, mutect2
- MAPKBP1 | c.3477C>T p.S1159= (on ENST00000456763 / NM_001128608.2; = p.S1153= on NM_014994.3) | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV52966162; called by muse, mutect2, varscan2
- NEMF | c.180A>G p.T60= | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as rs1267773787, COSV53594489; called by muse, mutect2
- STXBP4 | c.27A>G p.V9= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV54843334; called by muse, mutect2, varscan2
- TRIM32 | c.273C>T p.L91= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as rs766289627, COSV57809478; called by muse, mutect2, varscan2
- TYR | c.465C>A p.T155= | Silent (SNP) | VAF 51/128 reads (40%) | catalogued as rs775182073, COSV54483606; called by muse, mutect2, varscan2
